MMRF case MMRF_1501 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/02fdd4d5-2ded-4624-b999-49587396d590

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 891 days (2.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.3 years (23,856 days); ISS stage: II; Days to last known disease status: 891 days (2.4 years); Days to last follow up: 891 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 375 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 314 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 224 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 224 days; Days to treatment end: 671 days (1.8 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 375 days (1.0 years); Days to treatment end: 504 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 448 days (1.2 years); Days to treatment end: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 504 days (1.4 years); Days to treatment end: 734 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 606 days (1.7 years); Days to treatment end: 622 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 622 days (1.7 years); Days to treatment end: 874 days (2.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 891.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 374 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 61.8 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 5.34 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 318 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 3.28 mmol/L; Albumin 24 g/L; Total Protein 11.1 g/dL; Glucose 5.83 mmol/L; C-Reactive Protein 4.74 mg/dL.
- Day 94 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 9.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.968 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.87 g/L; Lactate Dehydrogenase 6.37 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 6.6 g/dL; Glucose 5.94 mmol/L.
- Day 196 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 6.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 8.94 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 6.49 mmol/L.
- Day 273 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 6.83 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 370 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.68 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 6.82 mmol/L.
- Day 448: M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 120 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 28.1 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.58 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 385 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 7.8 g/dL; Glucose 8.64 mmol/L.
- Day 545 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 154 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 30.8 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 7.1 g/dL; Glucose 6.33 mmol/L.
- Day 629 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 369 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 29 g/L; Total Protein 5.7 g/dL; Glucose 7.37 mmol/L.
- Day 704 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 30 g/L; Total Protein 5.6 g/dL; Glucose 8.91 mmol/L.
- Day 776 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 10.1 mmol/L.
- Day 873: M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 302 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 51.2 mg/dL; Immunoglobulin G 33.6 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 2.98 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.55 ×10⁹/L; Platelets 14 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Glucose 9.41 mmol/L.

Other clinical attributes
- Day -2: Weight: 93 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_1501_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1501_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
